Surgical pathology report (de-identified scan), TCGA case TCGA-IB-7888, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-7888-01A (Primary Tumor).

[page 1 of 4]
HISTOPATHOLOGY REPORT

ORIGINAL REPORT

SPECIMEN:

- A. Gallbladder.
- B. Head of pancreas and duodenum.

CLINICAL HISTORY:

Pancreas cancer.

DIAGNOSIS:

A. GALLBLADDER:

- CHOLECYSTITIS.
- CHOLELITHIASIS, MULTIPLE CHOLESTEROL STONES.

B. HEAD OF PANCREAS AND DUODENUM, WHIPPLE'S RESECTION:

- DUCTAL ADENOCARCINOMA, MODERATELY DIFFERENTIATED.
- TUMOR SIZE: 3.0 CM APPROXIMATE MAXIMUM DIMENSION (SLIDES B30, 31, 32)
- TUMOR LOCATION: HEAD OF PANCREAS.
- PERINEURAL INVASION: ABSENT.
- ANGIOLYMPHATIC INVASION: ABSENT.
- MARGINS: COMMON BILE DUCT, NEGATIVE FOR MALIGNANCY.
- PANCREATIC DUCT, NEGATIVE FOR MALIGNANCY.
- SOFT TISSUE, RETROPERITONEAL MARGIN, NEGATIVE FOR MALIGNANCY.
- PANCREATIC RESECTION MARGIN, NEGATIVE FOR MALIGNANCY.
- INVOLVEMENT OF ADJACENT STRUCTURES: TUMOR IS SEEN IN THE AMPULLA OF VATER AND INVOLVING THE MUCOSAL SURFACE AT THAT LOCATION
- LYMPH NODES: 12 LYMPH NODES, NEGATIVE FOR MALIGNANCY.
- CHRONIC PANCREATITIS.

[page 2 of 4]
HISTOPATHOLOGY REPORT

Division Head:

GROSS DESCRIPTION:

A. The specimen consists of a gallbladder. The specimen measures 10.0 x 4.5 x 2.0 cm. The serosal surface is smooth. Upon opening the gallbladder pouch, there are multiple yellow lobulated stones within the lumen, with brown to yellow sludge. The largest stone measures 1.0 x 1.0 x 1.0 cm. The stones vary in size with the smallest being 0.1 cm and appears grossly normal. Midway in the pouch, there is an area of narrowing 4.0 cm more proximally and 5.5 cm more distally to this narrowed area.

Representative sections are taken of the fundus, body, and the cystic duct. No cystic lymph node is identified.

B. The specimen has been painted with silver nitrate. The pancreatic resection margin is painted black and the uncinate margin is painted with blue ink. Photographs have been taken. Four pieces of tumor with two pieces of normal tissue have been taken for the [REDACTED]

The specimen consists of tan-yellow fibrofatty tissue that measures 39.0 x 32.0 x 1.2 cm. The next section consists of pylorus with duodenum that measures 24.0 cm. At the proximal margin it measures 6.0 cm in circumference, and distally measures 3.0 cm in circumference. The duodenal mucosa appears normal. The possible ampulla vater appears firm. The mucosa, more proximal to the ampulla of vater, is flattened. There are no areas of hemorrhage or polyps, or invasive tumor grossly identified.

The pancreatic head measures 7.0 x 5.0 x 4.5 cm. The common bile duct is dilated and measures 1.7 cm in diameter. The pancreatic duct measures 0.3 cm in diameter. There is attached mesentery that measures 8.0 x 4.0 x 1.2 cm. Within the pancreatic head, a firm white mass that appears to replace the normal pancreas is identified.

The pancreatic margin measures 3.2 x 2.0 cm. The uncinate margin that is painted measures 5.0 x 2.5 cm. The lesion in the pancreatic head is seen in the pancreatic neck and in the uncinate measuring 5.0 cm from the anterior to the posterior in greatest dimension, appears to involve the posterior margin, and is 0.1 cm away from the anterior margin. From superior to inferior, the tumor measures 5.5 cm. Grossly it appears to involve the pancreatic resection margin. It is 0.3 cm away from the inferior margin. Both the common bile duct and the pancreatic duct is encircled by the lesion. The common bile duct is dilated throughout. The ampulla of vater is probed and is difficult to insert the probe, and grossly appears to be patent. A 3.0 x 3.0 section

[page 3 of 4]
HISTOPATHOLOGY REPORT

GROSS DESCRIPTION:

around the ampulla of vater is removed for further serial sections. With the tumor, it also appears to be at the superior margin. Please note, the tumor is also 3.0 cm in depth. Specimen is submitted as follows:

- B1. perpendicular section of proximal margin
- B2. perpendicular section of distal margin
- B3. common bile duct enface
- B4. pancreatic resection margin, shaved
- B5. representative sections of superior margin with tumor
- B6. closest involvement of anterior margin with tumor
- B7. posterior margin with tumor
- B8. inferior margin with possibly normal pancreatic tissue
- B9. possible normal pancreatic tissue with adipose tissue
- B10. tumor with common bile duct and pancreatic duct
- B11. representative sections of tumor
- B12. representative sections of tumor

Please note within the duodenal mucosa, there is a lighter area of coloring that is more tan measuring 6.0 x 4.0 cm, is 12.0 cm from the distal margin, and 6.5 cm away from the proximal margin.

- B13. transition between light to dark mucosa
- B14-17. serial sections of the 3.0 x 3.0 cm section of ampulla of vater

A large common bile duct node measuring 2.2 x 1.7 x 0.8 cm.

- B18-19. trisected common bile duct lymph node
- B20. representative section of common bile duct
- B21-24. possible peripancreatic lymph nodes
- B25. bisected periduodenal lymph node
- B26. bisected periduodenal lymph node
- B27. possible two periduodenal lymph nodes
- B28. bisected periduodenal lymph node
- B29. periduodenal lymph node

Additional sections are submitted as follows:

- B30-32. section adjacent to removed ampulla block. Section grossly measured 2.4 cm in width. A firm area is identified 0.8 cm from the duodenal mucosa.

[page 4 of 4]
HISTOPATHOLOGY REPORT

GROSS DESCRIPTION:

B33-35. adjacent section to section in B30-B32.

An area of induration is appreciated by the common bile duct.

RESIDENT:

Source: NCI Genomic Data Commons file 7e32b5ca-120d-4b1b-ad39-aa39ecea33ad (TCGA-IB-7888.29A3F9C4-E362-45E2-AD2A-048B23C362F7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).